Surgical pathology report (de-identified scan), TCGA case TCGA-IB-A5SS, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-A5SS-01A (Primary Tumor).

[page 1 of 3]
Note: If you do not see "END OF PRINTED REPORT" at the bottom of the
the report **YOU DO NOT HAVE THE ENTIRE REPORT**. Please try printin

DOB

CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected

Time Reported

Order Number

Status

Final

Ordering Provider

Relevant
Information
Location

Copied To

Report Patient
Demographics
(for verification
purposes)

Name:

Date of Birth

Sex: F

ICD-O-3

Adenocarcinoma, duct NOS
Site: Tail of pancreas
C25.0

JW 4/2/13

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist

Specimen Description

A: #8 lymph node
B: Distal pancreas and spleen

Clinical Information

History pancreatic cancer (adjacent to aorta)

Diagnosis

A. #8 Lymph Node, Excision:

- One lymph node, negative for malignancy (0/1)

B. Distal Pancreas and Spleen, Resection:

- Poorly differentiated pancreatic ductal adenocarcinoma
- Tumor measures 4.5 cm in maximum dimension and extends into the peripancreatic adipose tissue (pT3)
- The cancer extends to the anterior and posterior edges of the pancreas
- The pancreatic surgical margin is negative for in situ and invasive carcinoma
- Positive for perineural and lymphovascular space invasion
- Six lymph nodes are identified, five of the six are positive for metastatic carcinoma (5/6), pN1
- Adenocarcinoma in situ is associated with the invasive tumor
- Intraductal papillary mucinous neoplasm is present in the pancreatic tail
- See Synoptic Report and Microscopic Description

[page 2 of 3]
- The spleen is unremarkable

Electronically signed by:

Synoptic Report

B: Pancreas (Exocrine), Macroscopic

SPECIMEN:

Tail of pancreas

Spleen

PROCEDURE:

Partial pancreatectomy (pancreatic tail) and splenectomy

TUMOR SITE:

Pancreatic body

Pancreatic tail

TUMOR SIZE:

Greatest dimension: 4.5 cm

Additional dimensions: 2.4 x 1.6 cm

B: Pancreas (Exocrine), Microscopic

HISTOLOGIC TYPE:

Ductal adenocarcinoma

HISTOLOGIC GRADE:

G3: Poorly differentiated

MICROSCOPIC TUMOR EXTENSION:

Tumor invades peripancreatic soft tissues

Tumor invades other peripancreatic soft tissue:

Tumor nodules are present in fat on the posterior surface. This may represent replacement of a lymph node.

Tumor invades other adjacent organs or structures:

Tumor invades the wall of the splenic artery and tumor embolus is present within the lumen of the splenic artery.

MARGINS:

Margins uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 8 mm

Specified margin: Pancreatic margin

Margins uninvolved by carcinoma in situ

Invasive carcinoma involves posterior retroperitoneal surface of pancreas

TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):

No prior treatment

LYMPH-VASCULAR INVASION:

Present

PERINEURAL INVASION:

Present

PRIMARY TUMOR (pT):

pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery

REGIONAL LYMPH NODES (pN):

pN1: Regional lymph node metastasis

Number examined: 6

Number involved: 5

DISTANT METASTASIS (pM):

Not applicable

ADDITIONAL PATHOLOGIC FINDINGS:

Pancreatic intraepithelial neoplasia (highest grade: PanIN 3)

Chronic pancreatitis

Intraductal papillary mucinous neoplasm present in the tail of the pancreas.

CLINICAL HISTORY:

Not specified

[page 3 of 3]
Gross Description

Received are specimens A and B. All requisitions and specimen containers are labelled with the patient's name. The cassettes and AP identifiers are labelled with the Surgical Number

A: The specimen consists of a single lymph node with a small amount of fatty tissue. The lymph node measures 2 x 1 x 0.5 cm. The lymph node is bisected and the cut surface is tan and grossly unremarkable. The two halves of the lymph node are submitted in toto in A1. The fatty tissue is submitted in A2.

B: The specimen consists of the spleen along with a portion of pancreas. The spleen measures 15 x 8 x 3.5 cm and the portion of pancreas measures 9 x 5.5 x 2.5 cm. The pancreas has been painted as follows: anterior surface blue, stapled medial resection margin orange, and the posterior surface black. Sectioning through the pancreas reveals a relatively well circumscribed tan slightly whorled appearing mass which measures 4.5 x 2.4 x 1.6 cm. The mass appears to encase the splenic vein and abuts the splenic artery. The tumor is less than 1 mm from the posterior pancreatic surface. The staples are carefully removed from the pancreatic resection margin. Minimal pancreatic tissue is removed with the staples. The mass is located 0.8 cm from the pancreatic resection margin and 1 cm from the spleen. Sectioning through the tail of the pancreas reveals that there are several small cystic structures present at the distal edge of the tumor. Sections are submitted as follows:

- B1-7. perpendicular sections through the pancreatic resection margin. Margin submitted in toto and shows the relationship of the margin to the tumor mass
- B8-13. representative sections perpendicular through the tumor showing the relationship of the tumor to the anterior and posterior surgical plane
- B14-19. sagittal sections taken through the tail of the pancreas showing the cystic areas
- B20-22. sections of the spleen where the tail of the pancreas intersects with the splenic hilum

Microscopic Description

Sections show a poorly differentiated ductal adenocarcinoma arising in the tail of the pancreas. Pancreatic adenocarcinoma in situ (PanIN 3) is identified at the edge of the invasive tumor. This area is located 1.1 cm from the pancreatic resection margin. Low grade pancreatic intraepithelial neoplasia is present at the pancreatic resection margin. The cytomorphology of the lesion is consistent PanIN 2. The invasive component replaces the tail of the pancreas and extends out into the peripancreatic soft tissue. Invasive carcinoma is identified at the inked anterior and posterior surfaces of the pancreas. Within the tail of the pancreas there is also an intraductal papillary mucinous neoplasm (IPMN) identified. Invasive ductal adenocarcinoma is seen surrounding the IPMN. The invasive component also invades into the wall of the splenic artery and tumor embolus is present within the lumen of the splenic artery. Six lymph nodes are identified in the peripancreatic fatty tissue of the tail. Five of the six lymph nodes are positive for metastatic ductal adenocarcinoma.

Accession
Number
Encounter
Number
Patient Location

- END OF PRINTED REPORT -

Source: NCI Genomic Data Commons file 93a72f3b-7014-40e0-8188-4903d55c8f96 (TCGA-IB-A5SS.9A82F47C-BD4B-4773-A6CF-885CE56D491E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).